Somatic mutation profile of tumor specimen C3L-02708-01 (aliquot CPT0189570007) from CPTAC case C3L-02708, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 43.8 years (16,016 days).
Specimen C3L-02708-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8e7f90a0-cad4-4507-84b6-e658f5bc7d12.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02708-31 (Blood Derived Normal), aliquot CPT0190620002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/be1a9e25-92a9-481c-8102-169bdc5038c0

The open-access MAF lists 75 somatic variants for this specimen: 52 protein-altering or splice-affecting, 13 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 13, Frame Shift Del 10, Intron 5, In Frame Del 3, Nonsense Mutation 3, 5'UTR 2, RNA 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- F8 | c.5113C>T p.Q1705* | Nonsense Mutation (SNP) | VAF 10/66 reads (15%) | catalogued as rs137852361, CM900093; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 85/216 reads (39%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 30/35 reads (86%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 401/453 reads (89%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- DDC | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 71/533 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs752108612, COSV63564210, COSV63568522; called by muse, mutect2, varscan2
- EPHA8 | c.1511C>T p.P504L | Missense Mutation (SNP) | VAF 116/324 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs761039847; called by muse, mutect2, varscan2
- GCSAM | c.439G>T p.E147* | Nonsense Mutation (SNP) | VAF 13/251 reads (5%) | catalogued as COSV58263806; called by muse, mutect2
- HYAL4 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.321); catalogued as rs766347554, COSV56138716; called by muse, mutect2, varscan2
- ISLR2 | c.1210C>T p.R404W | Missense Mutation (SNP) | VAF 46/338 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); catalogued as rs1160059898; called by muse, mutect2, varscan2
- KLK8 | c.721G>A p.V241I | Missense Mutation (SNP) | VAF 98/403 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs56296296; called by muse, mutect2, varscan2
- KYNU | c.1123A>G p.N375D | Missense Mutation (SNP) | VAF 58/145 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs1160444700; called by muse, mutect2, varscan2
- MAP1A | c.5864_5865del p.E1955Afs*6 | Frame Shift Del (DEL) | VAF 132/416 reads (32%) | catalogued as rs1566978902; called by pindel, varscan2
- MUC5B | c.5342C>T p.T1781M | Missense Mutation (SNP) | VAF 95/658 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs370364390; called by muse, mutect2, varscan2
- PLCD1 | c.1698G>T p.E566D | Missense Mutation (SNP) | VAF 22/424 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1310460402; called by muse, mutect2
- RBM27 | c.1577T>C p.M526T | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as rs774146717; called by muse, mutect2, varscan2
- SETD2 | c.1298G>A p.R433H | Missense Mutation (SNP) | VAF 77/202 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as rs764693453, COSV57443256, COSV57446331; called by muse, mutect2, varscan2
- SLC16A12 | c.1358G>C p.S453T | Missense Mutation (SNP) | VAF 118/264 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV57948466; called by muse, mutect2, varscan2
- SNX27 | c.1258A>G p.T420A | Missense Mutation (SNP) | VAF 75/159 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV64326816; called by muse, mutect2, varscan2
- TOP2A | c.86_89del p.S29Lfs*27 | Frame Shift Del (DEL) | VAF 14/132 reads (11%) | catalogued as rs763792949; called by pindel, varscan2
- TRAJ16 | c.43A>G p.M15V | Missense Mutation (SNP) | VAF 58/169 reads (34%) | catalogued as rs1173576492; called by muse, mutect2, varscan2
- ZNF335 | c.2744_2747del p.S915Tfs*3 | Frame Shift Del (DEL) | VAF 80/248 reads (32%) | catalogued as rs753460205; called by pindel, varscan2
- ZNF839 | c.641G>A p.R214Q (on ENST00000558850 / NM_001267827.1; = p.R330Q on NM_018335.5) | Missense Mutation (SNP) | VAF 97/230 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751268235; called by muse, mutect2, varscan2
- ACCSL | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 155/361 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- ADAMTS5 | c.2729C>T p.A910V | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); called by muse, mutect2
- APC2 | c.5620_5622del p.S1877del | In Frame Del (DEL) | VAF 52/130 reads (40%) | called by pindel, varscan2
- ARID2 | c.4271_4274del p.G1424Vfs*4 | Frame Shift Del (DEL) | VAF 53/184 reads (29%) | called by mutect2, pindel, varscan2
- ATRX | c.5811del p.D1940Ifs*15 | Frame Shift Del (DEL) | VAF 79/122 reads (65%) | called by mutect2, pindel, varscan2
- CFAP54 | c.8903G>T p.R2968I | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CHODL | c.136C>T p.H46Y | Missense Mutation (SNP) | VAF 82/182 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- COL4A5 | c.2281C>A p.P761T | Missense Mutation (SNP) | VAF 15/406 reads (4%) | SIFT tolerated (0.58); PolyPhen benign (0.005); called by muse, mutect2
- DALRD3 | c.655_657del p.K219del (on ENST00000341949 / NM_001009996.3; = p.K52del on NM_018114.5) | In Frame Del (DEL) | VAF 57/426 reads (13%) | called by mutect2, pindel, varscan2
- ECPAS | c.137_139del p.E46del | In Frame Del (DEL) | VAF 57/165 reads (35%) | called by pindel, varscan2
- FASN | c.5929_5930del p.D1977Wfs*35 | Frame Shift Del (DEL) | VAF 152/714 reads (21%) | called by pindel, varscan2
- GPD2 | c.606A>C p.E202D | Missense Mutation (SNP) | VAF 17/419 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.057); called by muse, mutect2
- IREB2 | c.2140_2141del p.K714Vfs*11 | Frame Shift Del (DEL) | VAF 26/99 reads (26%) | called by mutect2, pindel, varscan2
- KAT6B | c.5923C>T p.P1975S | Missense Mutation (SNP) | VAF 36/780 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.061); called by muse, mutect2
- MCM6 | c.1085A>G p.D362G | Missense Mutation (SNP) | VAF 97/222 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- MCTP2 | c.94C>A p.P32T | Missense Mutation (SNP) | VAF 142/388 reads (37%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- MMRN2 | c.1610A>G p.Q537R | Missense Mutation (SNP) | VAF 40/243 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- N4BP2 | c.1685G>T p.S562I | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- NEK10 | c.1055C>T p.S352F | Missense Mutation (SNP) | VAF 49/363 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NF1 | c.3061_3064del p.V1021* | Frame Shift Del (DEL) | VAF 20/142 reads (14%) | called by mutect2, pindel, varscan2
- NFX1 | c.305A>G p.Q102R | Missense Mutation (SNP) | VAF 261/303 reads (86%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- OR5A2 | c.202T>C p.S68P | Missense Mutation (SNP) | VAF 93/164 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- PTGDR | c.980G>A p.R327K | Missense Mutation (SNP) | VAF 108/313 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- RGPD1 | c.2614T>C p.Y872H (on ENST00000409776; = p.Y880H on NM_001024457.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- RGPD4 | c.2662T>C p.Y888H | Missense Mutation (SNP) | VAF 35/211 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- RPLP0 | c.631_632del p.L211Afs*52 | Frame Shift Del (DEL) | VAF 102/363 reads (28%) | called by pindel, varscan2
- RYR3 | c.9219C>A p.Y3073* (on ENST00000389232; = p.Y3074* on NM_001036.6) | Nonsense Mutation (SNP) | VAF 40/337 reads (12%) | called by muse, mutect2, varscan2
- SLTM | c.2312_2313del p.F771* | Frame Shift Del (DEL) | VAF 88/253 reads (35%) | called by pindel, varscan2
- ZDHHC16 | c.646T>A p.Y216N | Missense Mutation (SNP) | VAF 65/310 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ZNF560 | c.1948C>A p.H650N | Missense Mutation (SNP) | VAF 59/149 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CPLANE1 | c.7875A>G p.L2625= | Silent (SNP) | VAF 83/179 reads (46%) | called by muse, mutect2, varscan2
- DEFB112 | c.249G>T p.G83= | Silent (SNP) | VAF 69/142 reads (49%) | called by muse, mutect2, varscan2
- EPPK1 | c.2781C>T p.C927= | Silent (SNP) | VAF 19/306 reads (6%) | catalogued as rs781847412; called by muse, mutect2
- GJC1 | c.1137C>T p.N379= | Silent (SNP) | VAF 22/134 reads (16%) | called by muse, mutect2
- IRAG2 | c.3972C>T p.T1324= (on ENST00000636465; = p.T369= on NM_006152.4 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 39/275 reads (14%) | catalogued as COSV100209562; called by muse, mutect2, varscan2
- LINGO4 | c.1467C>T p.V489= | Silent (SNP) | VAF 112/281 reads (40%) | catalogued as rs751499899; called by muse, mutect2, varscan2
- LRP2 | c.2208T>C p.V736= | Silent (SNP) | VAF 138/347 reads (40%) | called by muse, varscan2
- MAST4 | c.5433C>T p.S1811= (on ENST00000403625 / NM_001164664.2; = p.S1622= on NM_015183.3) | Silent (SNP) | VAF 136/360 reads (38%) | catalogued as rs1303536143, COSV55130643; called by muse, mutect2, varscan2
- PCDHA13 | c.732A>G p.Q244= | Silent (SNP) | VAF 71/155 reads (46%) | called by muse, mutect2, varscan2
- POM121L12 | c.576C>T p.F192= | Silent (SNP) | VAF 132/369 reads (36%) | catalogued as rs762091356, COSV68692173; called by muse, mutect2, varscan2
- RNASEL | c.460A>C p.R154= | Silent (SNP) | VAF 217/607 reads (36%) | called by muse, mutect2, varscan2
- TMPRSS3 | c.309C>T p.D103= | Silent (SNP) | VAF 272/626 reads (43%) | catalogued as rs111033502; ClinVar: likely benign; called by muse, mutect2, varscan2
- TRIM64B | c.933A>C p.G311= | Silent (SNP) | VAF 138/520 reads (27%) | called by muse, mutect2, varscan2
- ABCD3 | c.828-14A>T | Intron (SNP) | VAF 50/120 reads (42%) | called by muse, mutect2, varscan2
- CCDC173 | c.68-72G>A | Intron (SNP) | VAF 49/123 reads (40%) | catalogued as rs754370821; called by muse, mutect2, varscan2
- HHLA1 | c.140-1071dup | Intron (INS) | VAF 68/204 reads (33%) | called by mutect2, pindel, varscan2
- LINC00583 | n.126G>T | RNA (SNP) | VAF 14/338 reads (4%) | called by muse, mutect2
- MTSS2 | c.*2389_*2391del | 3'UTR (DEL) | VAF 56/128 reads (44%) | called by pindel, varscan2
- OR10AB1P | n.755G>A | RNA (SNP) | VAF 37/269 reads (14%) | catalogued as rs761472850; called by muse, mutect2, varscan2
- RSPO3 | c.-1T>C | 5'UTR (SNP) | VAF 65/135 reads (48%) | called by muse, mutect2, varscan2
- STAT3 | c.1654-17A>G | Intron (SNP) | VAF 163/506 reads (32%) | called by muse, mutect2, varscan2
- TGIF1 | c.-98C>G | 5'UTR (SNP) | VAF 172/413 reads (42%) | called by muse, mutect2, varscan2
- TOMM7 | c.103+445_103+447del | Intron (DEL) | VAF 37/106 reads (35%) | called by pindel, varscan2
